Somatic mutation profile of tumor specimen TCGA-CV-6933-01A (aliquot TCGA-CV-6933-01A-11D-1912-08) from TCGA case TCGA-CV-6933, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 53.4 years (19,518 days).
Specimen TCGA-CV-6933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c003a5cd-91c7-4520-a363-61beb376f09c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6933-10A (Blood Derived Normal), aliquot TCGA-CV-6933-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f9d9821-543b-4e31-b584-6f9532097201

The open-access MAF lists 127 somatic variants for this specimen: 95 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 29, Nonsense Mutation 10, Nonstop Mutation 2, Frame Shift Ins 2, RNA 2, In Frame Ins 1, Frame Shift Del 1, Intron 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.10702C>G p.L3568V | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs549528540, COSV101315803; called by muse, mutect2, varscan2
- AGBL5 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100549053; called by muse, mutect2, varscan2
- ALKBH8 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs772973114, COSV99508728; called by muse, mutect2, varscan2
- ANKRD17 | c.6482A>T p.Q2161L | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV100429015; called by muse, mutect2, varscan2
- APBA1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.486); catalogued as rs1166715096, COSV99595941; called by muse, mutect2, varscan2
- ASMT | c.572G>C p.G191A (on ENST00000381229; = p.G219A on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767307366, COSV101172448; called by muse, mutect2, varscan2
- BEND5 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100884104; called by muse, mutect2, varscan2
- BPNT1 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as rs1012679128, COSV99070933; called by muse, mutect2, varscan2
- BYSL | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV99539825; called by muse, mutect2, varscan2
- C3AR1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756665372, COSV99368443; called by muse, mutect2, varscan2
- CDCA2 | c.3025C>G p.L1009V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV100398838; called by muse, mutect2, varscan2
- CEACAM18 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV101140325; called by muse, mutect2, varscan2
- CHST4 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749651712, COSV58296792; called by muse, mutect2, varscan2
- CNGA1 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs759487836, COSV62053254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A5 | c.4039G>T p.E1347* | Nonsense Mutation (SNP) | VAF 54/82 reads (66%) | catalogued as COSV100087501, COSV60364857; called by muse, mutect2, varscan2
- COQ10A | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV100369962; called by muse, mutect2, varscan2
- CSMD3 | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.255); catalogued as COSV52205994; called by muse, mutect2, varscan2
- DCSTAMP | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as COSV99886501; called by muse, mutect2, varscan2
- DIAPH3 | c.2784G>T p.Q928H (on ENST00000400324 / NM_001042517.2; = p.Q665H on NM_030932.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99933324; called by muse, mutect2, varscan2
- DMP1 | c.1542G>C p.*514Yext*5 | Nonstop Mutation (SNP) | VAF 35/174 reads (20%) | catalogued as COSV99218674; called by muse, mutect2, varscan2
- DOP1A | c.5157G>A p.M1719I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99381708; called by muse, varscan2
- DPP10 | c.964A>C p.T322P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100063656; called by muse, mutect2, varscan2
- EEF1A2 | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1555883506, COSV53208342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHD1 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV100276987; called by muse, mutect2, varscan2
- ESRRB | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as COSV99835161; called by muse, mutect2, varscan2
- FBN3 | c.2439G>A p.W813* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99560755; called by muse, mutect2, varscan2
- FLG | c.1214C>G p.A405G | Missense Mutation (SNP) | VAF 149/516 reads (29%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.972); catalogued as COSV100911501; called by muse, mutect2, varscan2
- FOXO1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.408); catalogued as COSV101091954; called by muse, mutect2, varscan2
- GBP7 | c.738A>T p.L246F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99643063; called by muse, mutect2, varscan2
- GLYATL1 | c.901C>G p.P301A (on ENST00000317391 / NM_001354699.1; = p.P332A on NM_080661.4) | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV55607632; called by muse, mutect2
- ICAM2 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56743514; called by muse, mutect2, varscan2
- IFT43 | c.626G>C p.*209Sext*13 (on ENST00000314067 / NM_001102564.3; = p.*214Sext*13 on NM_052873.3) | Nonstop Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as COSV99465989; called by muse, mutect2
- KCNH7 | c.3463C>A p.H1155N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); catalogued as COSV100147737; called by muse, mutect2, varscan2
- KIZ | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV99852038; called by muse, mutect2, varscan2
- KRTAP10-4 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV100553214; called by muse, mutect2, varscan2
- LEMD3 | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100384289; called by muse, mutect2, varscan2
- LRP12 | c.163del p.R55Efs*6 | Frame Shift Del (DEL) | VAF 13/107 reads (12%) | catalogued as COSV52633496; called by mutect2, pindel, varscan2
- LRRC28 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1567697515, COSV100113515; called by muse, mutect2, varscan2
- MAGEL2 | c.3307T>C p.S1103P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs1028803713, COSV100045892; called by muse, mutect2, varscan2
- MAPK4 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 37/69 reads (54%) | catalogued as COSV101245388; called by muse, mutect2, varscan2
- MEF2B | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50763984, COSV99364605; called by muse, mutect2, varscan2
- MTOR | c.1804T>C p.F602L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV100816067; called by muse, mutect2, varscan2
- MYSM1 | c.2084A>G p.Y695C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1163697160, COSV101284039; called by muse, mutect2, varscan2
- NDN | c.781T>C p.F261L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.079); catalogued as COSV100086414, COSV59361916; called by muse, mutect2
- NDNF | c.943T>A p.F315I | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101113156; called by muse, mutect2, varscan2
- NID2 | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99356407; called by muse, mutect2, varscan2
- NINL | c.2177A>G p.H726R | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV99625215; called by muse, mutect2, varscan2
- NKX2-4 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as rs1303485262, COSV100698596; called by muse, mutect2, varscan2
- NMT2 | c.1404G>C p.K468N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754309634, COSV100975523; called by muse, mutect2, varscan2
- NXF1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as rs1308263602, COSV99586001; called by muse, mutect2
- OLFM4 | c.280T>A p.F94I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.638); catalogued as COSV99524295; called by muse, mutect2, varscan2
- OR10H2 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374921134, COSV59945527; called by muse, mutect2, varscan2
- OR2T12 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV100527466, COSV58777823; called by muse, mutect2, varscan2
- PAPPA | c.2732+1G>T p.X911_splice | Splice Site (SNP) | VAF 49/160 reads (31%) | catalogued as COSV100073846; called by muse, mutect2, varscan2
- PFKFB2 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | PolyPhen possibly damaging (0.726); catalogued as COSV100891940; called by muse, mutect2
- PGM3 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV99392323; called by muse, mutect2, varscan2
- PHC1 | c.2978A>T p.K993M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99134165; called by muse, varscan2
- PIK3CG | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.418); catalogued as rs758968659, COSV63246501, COSV63247127; called by muse, mutect2, varscan2
- PLCB4 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99595261; called by muse, mutect2, varscan2
- POLR2G | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 29/360 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV57135239; called by muse, mutect2
- PPFIA2 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV100333000; called by muse, mutect2, varscan2
- PPP2R5A | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398030746, COSV99806597; called by muse, mutect2, varscan2
- PRPF4B | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs755637217, COSV100528148; called by muse, mutect2, varscan2
- PRRC2B | c.1859A>G p.Y620C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100621727; called by muse, mutect2, varscan2
- PTPN21 | c.2177G>C p.R726P | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100161843; called by muse, mutect2
- PTPRK | c.1549C>G p.P517A | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV100950898, COSV63895339; called by muse, mutect2, varscan2
- RIMS2 | c.2746C>G p.L916V (on ENST00000666250 / NM_001348490.2; = p.L724V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.645); catalogued as COSV99167490; called by muse, mutect2
- RRAGD | c.303C>A p.C101* | Nonsense Mutation (SNP) | VAF 101/296 reads (34%) | catalogued as COSV100784544, COSV63268430; called by muse, mutect2, varscan2
- SACS | c.7070A>T p.E2357V | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV101207396; called by muse, mutect2, varscan2
- SCN1A | c.1643G>C p.R548T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV100320215; called by muse, mutect2, varscan2
- SETDB1 | c.3139G>A p.D1047N | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99644453; called by muse, mutect2, varscan2
- SLITRK1 | c.249T>A p.N83K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.695); catalogued as COSV100999926; called by muse, mutect2, varscan2
- SMG1 | c.3551A>G p.N1184S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.402); catalogued as COSV101245799; called by muse, mutect2, varscan2
- SPIDR | c.1871A>G p.K624R | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99854911; called by muse, mutect2, varscan2
- STEAP4 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 451/567 reads (80%) | catalogued as COSV100112546; called by muse, mutect2, varscan2
- SYNE2 | c.3749A>T p.H1250L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100647462; called by muse, mutect2, varscan2
- SYTL1 | c.1033G>T p.G345C (on ENST00000543823; = p.G333C on NM_032872.3) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100539288; called by muse, mutect2, varscan2
- THSD7A | c.826A>T p.R276* | Nonsense Mutation (SNP) | VAF 34/141 reads (24%) | catalogued as COSV101448682; called by muse, mutect2, varscan2
- TMTC3 | c.2735A>G p.N912S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as COSV99898291; called by muse, mutect2, varscan2
- TRPA1 | c.2438C>T p.T813M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs538354055, COSV51564490; called by muse, mutect2, varscan2
- TSC22D1 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101488101; called by muse, mutect2, varscan2
- WASF1 | c.1538A>G p.K513R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.908); catalogued as COSV100846837; called by muse, mutect2, varscan2
- WDR53 | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 87/384 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100218064; called by muse, mutect2, varscan2
- WDR64 | c.2975G>C p.R992T | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100843757; called by muse, varscan2
- ZBTB22 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99802002; called by mutect2, varscan2
- ZNF43 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100731793; called by muse, mutect2, varscan2
- ZNF479 | c.884G>C p.R295T | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV100482705, COSV58635981, COSV58638464; called by muse, mutect2
- ZRANB3 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV99923426; called by muse, mutect2
- HEATR5B | c.4667_4672dup p.S1556_G1557dup | In Frame Ins (INS) | VAF 24/106 reads (23%) | called by mutect2, varscan2
- KRTAP10-4 | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- KRTAP10-6 | c.270C>A p.C90* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | called by mutect2, varscan2
- NKAP | c.231_236del p.S80_R81del | In Frame Del (DEL) | VAF 10/15 reads (67%) | called by mutect2, varscan2
- NRCAM | c.2705dup p.I903Dfs*20 (on ENST00000379028 / NM_001371124.1; = p.I887Dfs*20 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 15/126 reads (12%) | called by mutect2, pindel, varscan2
- TFAP2A | c.717_718dup p.L240Rfs*29 (on ENST00000482890; = p.L232Rfs*29 on NM_001032280.3) | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | called by mutect2, pindel
- CDH19 | c.2301A>T p.A767= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100051421; called by muse, mutect2, varscan2
- CMYA5 | c.2814T>C p.D938= | Silent (SNP) | VAF 55/102 reads (54%) | catalogued as rs1322103038, COSV101484018; called by muse, mutect2, varscan2
- CNGB3 | c.2004G>A p.P668= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs142347723; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL22A1 | c.4797C>T p.P1599= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs776786087, COSV100278072; called by muse, mutect2, varscan2
- CYFIP2 | c.1152G>A p.E384= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs761547295, COSV100556593; called by muse, mutect2, varscan2
- DNM1L | c.1533T>C p.N511= | Silent (SNP) | VAF 56/206 reads (27%) | catalogued as rs377443517; called by muse, mutect2, varscan2
- DOCK5 | c.594C>T p.I198= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99376770; called by muse, mutect2, varscan2
- FAM47B | c.390C>T p.P130= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as rs1406348970, COSV100264277; called by muse, mutect2, varscan2
- FGFR4 | c.1005A>G p.A335= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV99449664; called by muse, mutect2, varscan2
- GAP43 | c.273C>T p.A91= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV100525523; called by muse, mutect2, varscan2
- GSS | c.742C>T p.L248= | Silent (SNP) | VAF 47/307 reads (15%) | catalogued as rs768185100, COSV99404396; called by muse, mutect2, varscan2
- H4C5 | c.153C>A p.I51= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV100747935, COSV100747982; called by muse, mutect2, varscan2
- KRTAP19-1 | c.186C>T p.Y62= | Silent (SNP) | VAF 38/355 reads (11%) | catalogued as rs571502343; called by muse, mutect2, varscan2
- LRP1B | c.7365T>A p.A2455= | Silent (SNP) | VAF 10/172 reads (6%) | catalogued as COSV101255949; called by muse, mutect2
- NLGN4X | c.1798T>C p.L600= | Silent (SNP) | VAF 53/95 reads (56%) | catalogued as COSV99321422; called by muse, mutect2, varscan2
- NPC1L1 | c.3468C>T p.L1156= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs1453255258, COSV99206618; called by muse, mutect2, varscan2
- OR2T6 | c.288C>A p.A96= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV63216669; called by muse, mutect2, varscan2
- OR4D5 | c.852T>C p.P284= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100189934; called by muse, mutect2, varscan2
- OR5F1 | c.456G>T p.G152= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV53546094, COSV99558566; called by muse, mutect2, varscan2
- OR6C1 | c.429T>G p.V143= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV101110495; called by muse, mutect2, varscan2
- PDHA2 | c.618C>T p.F206= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99756821; called by muse, mutect2, varscan2
- PLPPR4 | c.2241T>C p.T747= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100926782; called by muse, mutect2, varscan2
- PYGO1 | c.1164A>T p.A388= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV100114608; called by muse, mutect2, varscan2
- PZP | c.570C>G p.S190= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as COSV99737547; called by muse, mutect2, varscan2
- ROS1 | c.453G>A p.P151= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs777706763, COSV63853442; called by muse, mutect2, varscan2
- STK31 | c.2181A>G p.E727= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs1220357092, COSV100669321; called by muse, mutect2, varscan2
- TXNRD1 | c.1815G>A p.A605= (on ENST00000525566 / NM_001093771.3; = p.A507= on NM_003330.4) | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs764327204, COSV100723420; called by muse, mutect2, varscan2
- ZDHHC8 | c.267G>A p.P89= | Silent (SNP) | VAF 62/108 reads (57%) | catalogued as rs757280778, COSV100272764; called by muse, mutect2, varscan2
- ZNF250 | c.1314G>C p.L438= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99480824; called by muse, varscan2
- EEF1D | c.-7-2343G>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100414650; called by muse, mutect2
- HERC2P3 | n.897G>C | RNA (SNP) | VAF 42/209 reads (20%) | called by muse, mutect2, varscan2
- OR52A4P | n.653C>T | RNA (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
